Somatic mutation profile of cancer-model specimen HCM-SANG-0302-C15-85A (3D Organoid; aliquot HCM-SANG-0302-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0302-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0302-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5128fa88-824f-4149-9965-03f54aef1326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0302-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0302-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11252ad6-c4c4-43f3-96a8-1499aa97f164

The open-access MAF lists 306 somatic variants for this specimen: 226 protein-altering or splice-affecting, 73 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 73, Nonsense Mutation 16, Frame Shift Del 4, Intron 4, Frame Shift Ins 3, In Frame Del 3, Splice Region 2, Splice Site 1, 3'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 393/393 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.1073C>A p.T358N | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV55588099, COSV55590614; called by muse, varscan2
- ABCG5 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 164/522 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs778605187; called by muse, mutect2, varscan2
- AL133500.1 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 248/527 reads (47%) | SIFT deleterious, low confidence (0); catalogued as rs773210279, COSV55744446; called by muse, mutect2, varscan2
- ANK1 | c.2207G>T p.S736I | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99224826; called by muse, mutect2, varscan2
- ANKRD30A | c.3051A>C p.K1017N (on ENST00000611781; = p.K961N on NM_052997.2) | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV64603900, COSV64607723, COSV64608830; called by muse, mutect2, varscan2
- ASB5 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56674926; called by muse, mutect2
- AZGP1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs146017934; called by muse, mutect2, varscan2
- B9D2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 224/657 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV54684458; called by muse, mutect2, varscan2
- BMX | c.1821C>G p.S607R | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1265550312; called by muse, mutect2, varscan2
- C20orf141 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 72/1084 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767811381; called by muse, mutect2
- CACNG6 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 303/441 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.379); catalogued as COSV53167402; called by muse, mutect2, varscan2
- CCL25 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV99495201; called by muse, mutect2, varscan2
- CDH8 | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1242043001, COSV54854584; called by mutect2, varscan2
- CHST13 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 23/808 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1231021325, COSV60043121; called by muse, mutect2
- CLEC16A | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 171/551 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201076792, COSV55491109; called by muse, mutect2, varscan2
- CNTN6 | c.1067A>C p.E356A | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.559); catalogued as COSV63175998, COSV63176032; called by muse, mutect2, varscan2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by muse, varscan2
- CNTNAP5 | c.2495T>C p.L832P | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV70474139, COSV99081553; called by muse, varscan2
- COL4A1 | c.4471G>A p.G1491S | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs190510837; called by muse, mutect2, varscan2
- COL5A1 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 337/673 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs752334702, COSV65672618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPLX2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 137/447 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs760771461; called by muse, mutect2, varscan2
- CSMD1 | c.8693G>C p.R2898T (on ENST00000520002; = p.R2897T on NM_033225.6) | Missense Mutation (SNP) | VAF 102/523 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV59311210; called by muse, mutect2, varscan2
- DOCK2 | c.3173A>T p.K1058M | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- DYSF | c.4913C>G p.P1638R | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50266604; called by muse, mutect2, varscan2
- DZANK1 | c.1243-3C>A | Splice Region (SNP) | VAF 73/1087 reads (7%) | catalogued as rs1374476833; called by muse, mutect2
- EPS8 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs765146644; called by muse, mutect2, varscan2
- FGD4 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 144/227 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs886049255, COSV99847791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM2 | c.4507A>G p.K1503E | Missense Mutation (SNP) | VAF 54/590 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs779181685; called by muse, mutect2
- GALNT17 | c.1660T>G p.F554V | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100353835; called by muse, mutect2, varscan2
- GJA10 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV101005260; called by muse, mutect2, varscan2
- GMIP | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 215/327 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs145745438; called by muse, mutect2, varscan2
- IGKV1-5 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs371887060; called by muse, mutect2, varscan2
- IL12B | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs140131034; called by muse, varscan2
- INTS1 | c.5579C>T p.A1860V | Missense Mutation (SNP) | VAF 655/1123 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as rs756207848; called by muse, mutect2, varscan2
- IRX6 | c.723A>G p.E241= | Splice Region (SNP) | VAF 91/262 reads (35%) | catalogued as COSV51859141; called by muse, varscan2
- KCNC3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 169/588 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as rs1307290372; called by muse, mutect2, varscan2
- KCNK9 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 151/1022 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs753634595, COSV57277825, COSV57281383; called by muse, mutect2, varscan2
- KDR | c.2812T>C p.Y938H | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55769727; called by muse, mutect2, varscan2
- KIAA1549L | c.3295C>T p.R1099W (on ENST00000321505; = p.R1396W on NM_012194.3) | Missense Mutation (SNP) | VAF 419/737 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs541806560, COSV55779393; called by muse, mutect2, varscan2
- KIT | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV55397534; called by muse, mutect2, varscan2
- KRT27 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 139/551 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs779625142; called by muse, mutect2, varscan2
- LAMA2 | c.8299G>A p.G2767R | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779071476, COSV70355736; called by muse, mutect2, varscan2
- LUZP2 | c.804A>C p.Q268H | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100419385, COSV61195719; called by muse, mutect2, varscan2
- MAGEC1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 149/309 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs147835720, COSV53573381; called by muse, mutect2, varscan2
- MTF1 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs1357297031; called by muse, mutect2, varscan2
- MTF1 | c.1097C>A p.S366* | Nonsense Mutation (SNP) | VAF 31/223 reads (14%) | catalogued as COSV65989054; called by muse, mutect2, varscan2
- MUC5B | c.10965G>A p.M3655I | Missense Mutation (SNP) | VAF 72/1357 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs1250877005; called by muse, mutect2
- MYH4 | c.2999A>C p.K1000T | Missense Mutation (SNP) | VAF 466/470 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs1426812861, COSV55115994, COSV55127068; called by muse, mutect2, varscan2
- NDST4 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52107943; called by muse, mutect2
- NFATC3 | c.1970G>A p.G657E | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.027); catalogued as COSV60474342; called by muse, mutect2, varscan2
- NRP1 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as rs201841993; called by muse, mutect2, varscan2
- NXPE2 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 149/666 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64941019; called by muse, mutect2, varscan2
- OR11H12 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 103/530 reads (19%) | catalogued as COSV101612483; called by muse, mutect2, varscan2
- OR2M5 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 225/459 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100822831; called by muse, mutect2, varscan2
- OR5D18 | c.46T>G p.L16V | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV61737243; called by muse, mutect2, varscan2
- PACS2 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 52/735 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV100330640, COSV100330862; called by muse, mutect2
- PCDH15 | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777625219; called by muse, mutect2, varscan2
- PCDHB7 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 544/772 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV50756781; called by muse, mutect2, varscan2
- PDZRN4 | c.2816G>T p.R939L (on ENST00000402685 / NM_001164595.2; = p.R681L on NM_013377.4) | Missense Mutation (SNP) | VAF 244/367 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54193075; called by muse, mutect2, varscan2
- PLEKHO1 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 47/644 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV50311686; called by muse, mutect2
- PLXNC1 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138337903; called by muse, mutect2, varscan2
- PLXND1 | c.4183G>T p.E1395* | Nonsense Mutation (SNP) | VAF 107/512 reads (21%) | catalogued as COSV60717656; called by muse, mutect2, varscan2
- POU6F2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 42/718 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV68884828; called by muse, mutect2
- PPP1R3A | c.1129A>C p.S377R | Missense Mutation (SNP) | VAF 118/339 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV52888854; called by muse, mutect2, varscan2
- PRAMEF4 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 341/369 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52439288; called by muse, mutect2, varscan2
- PRKAG1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs780637267, COSV60292088; called by muse, mutect2, varscan2
- PSG7 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 146/510 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs747491077, COSV101343265, COSV68445724; called by muse, mutect2, varscan2
- PYGM | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 163/500 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs762305749; called by muse, mutect2, varscan2
- RAD54L2 | c.3596A>G p.N1199S | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs145367357; called by muse, mutect2, varscan2
- RGS7 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 163/335 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100464246, COSV58537660; called by muse, mutect2, varscan2
- RXFP3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 81/654 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV57503803; called by muse, mutect2, varscan2
- SFTPD | c.438A>C p.E146D | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100954460; called by muse, mutect2, varscan2
- SH3RF1 | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 205/391 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371090000; called by muse, mutect2, varscan2
- SLC26A11 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 163/699 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1018158432; called by muse, mutect2, varscan2
- SPTA1 | c.3782A>G p.Q1261R | Missense Mutation (SNP) | VAF 121/507 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100935612; called by muse, mutect2, varscan2
- STN1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830128; called by muse, mutect2, varscan2
- STXBP5 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs974699665; called by muse, mutect2
- TMEM30A | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 90/156 reads (58%) | catalogued as rs1195661994, COSV57874668; called by muse, mutect2, varscan2
- TUBG1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 62/330 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs748889906, COSV52223162; called by muse, mutect2, varscan2
- UNC80 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs750442854, COSV55884668, COSV55892124; called by muse, mutect2, varscan2
- ZC3H18 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 94/418 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV56323246; called by muse, mutect2, varscan2
- ZNF280A | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 430/430 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367622787; called by muse, mutect2, varscan2
- ZNF677 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs190940311; called by muse, mutect2, varscan2
- ZNF99 | c.1326del p.K442Nfs*4 | Frame Shift Del (DEL) | VAF 221/413 reads (54%) | catalogued as COSV101234000; called by mutect2, pindel, varscan2
- AATF | c.886T>G p.L296V | Missense Mutation (SNP) | VAF 56/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- AC008687.4 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 204/629 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ADAD2 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 236/623 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ADAM12 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 153/1527 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRG4 | c.8385G>T p.L2795F | Missense Mutation (SNP) | VAF 147/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AEBP1 | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 277/468 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.6410G>T p.G2137V | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMPH | c.150A>C p.E50D | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ANKRD30B | c.3650T>G p.V1217G | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2
- ASPM | c.4651C>G p.L1551V | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2
- AZIN1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 102/740 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHLHE22 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 224/1013 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- BNC1 | c.2824A>G p.T942A | Missense Mutation (SNP) | VAF 170/462 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CAPN10 | c.1759A>G p.R587G | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CAPN10 | c.1760G>T p.R587M | Missense Mutation (SNP) | VAF 37/448 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.325); called by muse, mutect2
- CCDC54 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDH2 | c.302A>T p.K101M | Missense Mutation (SNP) | VAF 122/736 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- CDH20 | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- CFTR | c.3022_3030del p.V1008_V1010del | In Frame Del (DEL) | VAF 69/251 reads (27%) | called by mutect2, pindel, varscan2
- CITED4 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CNTNAP4 | c.390+1del | Frame Shift Del (DEL) | VAF 49/149 reads (33%) | called by mutect2, pindel, varscan2
- CNTROB | c.1526A>G p.E509G | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, varscan2
- COL6A6 | c.694T>C p.F232L | Missense Mutation (SNP) | VAF 228/357 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- COLEC12 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 532/800 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP27A1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 177/515 reads (34%) | called by muse, mutect2, varscan2
- DCDC2C | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DDX54 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 141/466 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIO2 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 229/791 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); called by muse, varscan2
- DNAH17 | c.8326T>G p.F2776V | Missense Mutation (SNP) | VAF 37/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DYNC1I1 | c.1383A>T p.E461D | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EMD | c.377A>C p.D126A | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.208); called by muse, mutect2
- ENPP3 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- EPB41 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2
- EPHA5 | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.766A>T p.I256L | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.133); called by muse, varscan2
- FABP12 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 86/643 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- FAM155A | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 94/738 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.242); called by muse, varscan2
- FNBP1L | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 111/221 reads (50%) | called by muse, mutect2, varscan2
- FOXK1 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 325/819 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FREM2 | c.2926A>T p.T976S | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GCFC2 | c.2127dup p.W710Mfs*3 | Frame Shift Ins (INS) | VAF 74/280 reads (26%) | called by mutect2, pindel, varscan2
- GDF1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 195/543 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- GPAT3 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2
- GRIA2 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 186/298 reads (62%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK1 | c.1181C>G p.A394G | Missense Mutation (SNP) | VAF 35/375 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GRM3 | c.2610A>C p.E870D | Missense Mutation (SNP) | VAF 222/327 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- HEPN1 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 74/614 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HIVEP2 | c.4571A>C p.Q1524P | Missense Mutation (SNP) | VAF 173/613 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGF2R | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 42/379 reads (11%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 293/950 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- IGKV1D-42 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- IGKV3D-20 | c.136A>T p.S46C | Missense Mutation (SNP) | VAF 148/514 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILF3 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ING3 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.027); called by muse, mutect2
- IQCN | c.3260G>T p.G1087V | Missense Mutation (SNP) | VAF 117/703 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IRF7 | c.806_823del p.G269_P274del (on ENST00000397566; = p.G256_P261del on NM_001572.5) | In Frame Del (DEL) | VAF 106/308 reads (34%) | called by mutect2, pindel, varscan2
- KATNIP | c.2776G>C p.E926Q | Missense Mutation (SNP) | VAF 136/500 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- KCNA4 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 153/478 reads (32%) | called by muse, mutect2, varscan2
- KCNA5 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 203/412 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KCND2 | c.508A>T p.R170W | Missense Mutation (SNP) | VAF 64/604 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- KHDC4 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF21A | c.2833G>A p.A945T (on ENST00000361418 / NM_001378440.1; = p.A932T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIT | c.926-1_928del p.X309_splice | Splice Site (DEL) | VAF 42/106 reads (40%) | called by mutect2, pindel, varscan2
- KLRC2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRC52 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 77/526 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MAGEB5 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MALRD1 | c.4866del p.V1623Yfs*20 | Frame Shift Del (DEL) | VAF 48/239 reads (20%) | called by mutect2, pindel, varscan2
- MARCHF11 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 140/672 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBTD1 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRTFB | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MSH2 | c.2349_2374del p.H783Qfs*7 | Frame Shift Del (DEL) | VAF 44/452 reads (10%) | called by mutect2, pindel
- MTFR2 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDRG3 | c.505G>T p.G169C (on ENST00000349004 / NM_032013.4; = p.G157C on NM_022477.4) | Missense Mutation (SNP) | VAF 31/612 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- NFATC4 | c.1788C>A p.C596* | Nonsense Mutation (SNP) | VAF 181/778 reads (23%) | called by muse, mutect2, varscan2
- NUTM2D | c.1712T>G p.L571W | Missense Mutation (SNP) | VAF 191/2134 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); called by muse, mutect2
- OR12D1 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 220/363 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- OR1E1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 17/567 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR3A2 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR4S1 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 363/731 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- OR5M11 | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR8I2 | c.95T>A p.L32H | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAOX | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 154/488 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDH11X | c.2609A>G p.K870R | Missense Mutation (SNP) | VAF 306/307 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB5 | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 72/776 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- PCNX2 | c.4307G>C p.G1436A | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF3 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PINLYP | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 200/338 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCD3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 190/911 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXNA1 | c.5032A>T p.I1678F | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP3 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 209/211 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP1R3D | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 105/1188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSME3IP1 | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRO | c.729dup p.S244Efs*30 | Frame Shift Ins (INS) | VAF 129/330 reads (39%) | called by mutect2, pindel, varscan2
- RASL12 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 27/686 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- RFXAP | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 77/573 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RRP15 | c.502A>T p.R168W | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SAMSN1 | c.204A>C p.K68N | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SFRP4 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 117/559 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SGCD | c.27C>G p.H9Q (on ENST00000435422 / NM_001128209.2; = p.H10Q on NM_000337.5) | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC33A1 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 89/293 reads (30%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1653A>T p.K551N | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SNTG1 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 86/564 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX17 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 100/325 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SORCS1 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 28/489 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA31A1 | c.3810A>T p.Q1270H | Missense Mutation (SNP) | VAF 201/871 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- STOX2 | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SYNE2 | c.4048dup p.T1350Nfs*14 | Frame Shift Ins (INS) | VAF 216/680 reads (32%) | called by mutect2, pindel, varscan2
- SYT9 | c.1309T>G p.L437V | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TAFA3 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 194/392 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDG | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 109/177 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TEX13C | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 316/319 reads (99%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TFAP2B | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 77/254 reads (30%) | called by muse, mutect2, varscan2
- TLL1 | c.1874T>C p.L625P | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); called by muse, varscan2
- TLR4 | c.132T>G p.N44K (on ENST00000355622 / NM_138554.5; = p.N4K on NM_003266.4) | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TLR4 | c.570T>G p.I190M (on ENST00000355622 / NM_138554.5; = p.I150M on NM_003266.4) | Missense Mutation (SNP) | VAF 218/488 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TMEM236 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 118/423 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TMEM91 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 148/489 reads (30%) | called by muse, mutect2, varscan2
- TPTE2 | c.556A>T p.R186* (on ENST00000400230 / NM_199254.2; = p.R109* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- TRARG1 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 28/782 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.416); called by muse, mutect2
- TRARG1 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 28/779 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRIM71 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 183/378 reads (48%) | called by muse, mutect2, varscan2
- TRPA1 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 411/482 reads (85%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC28 | c.1729T>A p.Y577N | Missense Mutation (SNP) | VAF 27/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.8517A>T p.K2839N (on ENST00000591111; = p.K2793N on NM_003319.4) | Missense Mutation (SNP) | VAF 149/472 reads (32%) | PolyPhen benign (0.111); called by muse, mutect2, varscan2
- UBASH3A | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- UBC | c.709A>C p.T237P | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- UBE2D1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- VEGFD | c.217A>C p.S73R | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- VSIG10L2 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 90/838 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- WNK2 | c.4237C>T p.P1413S (on ENST00000297954 / NM_001282394.1; = p.P1376S on NM_006648.3) | Missense Mutation (SNP) | VAF 188/706 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- YLPM1 | c.5105T>G p.V1702G | Missense Mutation (SNP) | VAF 56/634 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2
- ZFYVE26 | c.6945_6956del p.T2316_R2319del | In Frame Del (DEL) | VAF 81/587 reads (14%) | called by mutect2, pindel, varscan2
- ZNF256 | c.945A>T p.R315S | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ZNF568 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF681 | c.406A>C p.T136P | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF728 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF729 | c.3599G>T p.C1200F | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF75A | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 122/381 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF804A | c.1493C>A p.S498* | Nonsense Mutation (SNP) | VAF 74/261 reads (28%) | called by muse, mutect2, varscan2
- ZRANB1 | c.1339T>G p.S447A | Missense Mutation (SNP) | VAF 149/469 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCA13 | c.10263C>A p.G3421= | Silent (SNP) | VAF 68/476 reads (14%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1239C>T p.D413= | Silent (SNP) | VAF 72/882 reads (8%) | catalogued as rs781523842; called by muse, mutect2
- ACTA1 | c.15C>T p.D5= | Silent (SNP) | VAF 96/394 reads (24%) | catalogued as rs1397255499, COSV100796794, COSV64202815; called by muse, mutect2, varscan2
- ADCY8 | c.1107A>G p.R369= | Silent (SNP) | VAF 75/328 reads (23%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2553C>T p.C851= | Silent (SNP) | VAF 46/243 reads (19%) | called by muse, mutect2, varscan2
- ANKZF1 | c.1308G>T p.R436= | Silent (SNP) | VAF 140/448 reads (31%) | called by muse, mutect2, varscan2
- APOB | c.12537T>C p.T4179= | Silent (SNP) | VAF 101/323 reads (31%) | called by muse, mutect2, varscan2
- ASXL3 | c.1125A>G p.G375= | Silent (SNP) | VAF 120/747 reads (16%) | called by muse, mutect2, varscan2
- BANK1 | c.1431T>C p.S477= | Silent (SNP) | VAF 145/402 reads (36%) | called by muse, mutect2, varscan2
- BHLHA9 | c.534G>A p.S178= | Silent (SNP) | VAF 54/432 reads (13%) | called by muse, mutect2, varscan2
- BMX | c.1822C>T p.L608= | Silent (SNP) | VAF 52/293 reads (18%) | called by muse, mutect2, varscan2
- CACNB1 | c.456G>A p.E152= | Silent (SNP) | VAF 56/1116 reads (5%) | called by muse, mutect2
- CCDC82 | c.1575T>C p.G525= | Silent (SNP) | VAF 139/283 reads (49%) | called by muse, mutect2, varscan2
- CDC42BPB | c.4788C>T p.G1596= | Silent (SNP) | VAF 81/770 reads (11%) | called by muse, mutect2, varscan2
- CFAP94 | c.654C>T p.N218= (on ENST00000320267 / NM_001352064.2; = p.N224= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/324 reads (31%) | called by muse, mutect2, varscan2
- CHST8 | c.774C>T p.R258= | Silent (SNP) | VAF 392/576 reads (68%) | called by muse, mutect2, varscan2
- COL1A1 | c.219G>T p.V73= | Silent (SNP) | VAF 180/732 reads (25%) | called by muse, mutect2, varscan2
- CUL7 | c.4545C>T p.H1515= | Silent (SNP) | VAF 1095/1338 reads (82%) | catalogued as rs374026887; called by muse, mutect2, varscan2
- CYP7B1 | c.184T>C p.L62= | Silent (SNP) | VAF 429/557 reads (77%) | catalogued as COSV100040924; called by muse, mutect2, varscan2
- DACH2 | c.555T>G p.R185= | Silent (SNP) | VAF 242/242 reads (100%) | called by muse, mutect2, varscan2
- DACT3 | c.876G>A p.A292= | Silent (SNP) | VAF 93/280 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | c.1215C>T p.D405= | Silent (SNP) | VAF 142/459 reads (31%) | catalogued as rs1220284219; called by muse, mutect2, varscan2
- DYNLL2 | c.63C>T p.A21= | Silent (SNP) | VAF 98/430 reads (23%) | catalogued as rs762025974; called by muse, mutect2, varscan2
- EDA2R | c.522T>G p.G174= | Silent (SNP) | VAF 123/267 reads (46%) | called by muse, mutect2, varscan2
- EFCAB8 | c.3621C>T p.A1207= | Silent (SNP) | VAF 258/1249 reads (21%) | called by muse, mutect2, varscan2
- GALNT5 | c.1104C>G p.S368= | Silent (SNP) | VAF 184/283 reads (65%) | called by muse, mutect2, varscan2
- GAREM1 | c.747G>A p.V249= | Silent (SNP) | VAF 102/902 reads (11%) | called by muse, mutect2, varscan2
- GAS2L2 | c.2136G>A p.K712= | Silent (SNP) | VAF 68/653 reads (10%) | called by muse, mutect2, varscan2
- GLIS3 | c.978C>T p.A326= | Silent (SNP) | VAF 198/424 reads (47%) | called by muse, mutect2, varscan2
- GPR158 | c.300C>T p.S100= | Silent (SNP) | VAF 202/639 reads (32%) | catalogued as rs761801989, COSV100892954; called by muse, mutect2, varscan2
- GRIA1 | c.2700C>A p.P900= | Silent (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- HECW1 | c.2058G>T p.S686= | Silent (SNP) | VAF 349/942 reads (37%) | catalogued as COSV67826461; called by muse, mutect2, varscan2
- HS3ST2 | c.279G>A p.V93= | Silent (SNP) | VAF 193/559 reads (35%) | called by muse, mutect2, varscan2
- IGHA1 | c.30G>A p.P10= | Silent (SNP) | VAF 129/1012 reads (13%) | catalogued as rs750572037; called by muse, mutect2, varscan2
- IGKV3D-20 | c.135C>A p.A45= | Silent (SNP) | VAF 146/514 reads (28%) | called by muse, mutect2, varscan2
- IL17C | c.126G>A p.L42= | Silent (SNP) | VAF 111/505 reads (22%) | called by muse, varscan2
- IRX1 | c.369C>T p.F123= | Silent (SNP) | VAF 137/624 reads (22%) | catalogued as COSV57362498, COSV57363137; called by muse, mutect2, varscan2
- KDM6B | c.1416C>T p.P472= | Silent (SNP) | VAF 132/408 reads (32%) | catalogued as rs766388585; called by muse, mutect2, varscan2
- KDR | c.2811C>A p.P937= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- LAMA1 | c.3681A>G p.G1227= | Silent (SNP) | VAF 36/626 reads (6%) | catalogued as rs760303299; called by muse, mutect2
- LHFPL4 | c.162C>A p.P54= | Silent (SNP) | VAF 187/632 reads (30%) | called by muse, varscan2
- MDGA2 | c.1863A>T p.G621= (on ENST00000399232 / NM_001113498.2; = p.G323= on NM_182830.4) | Silent (SNP) | VAF 64/530 reads (12%) | catalogued as COSV62100873; called by muse, mutect2, varscan2
- MGA | c.3105T>C p.P1035= | Silent (SNP) | VAF 193/314 reads (61%) | called by muse, mutect2, varscan2
- MTUS2 | c.771A>G p.S257= | Silent (SNP) | VAF 36/484 reads (7%) | called by muse, mutect2
- MUC17 | c.1176C>T p.S392= | Silent (SNP) | VAF 140/476 reads (29%) | called by muse, mutect2, varscan2
- MYEF2 | c.213T>A p.S71= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- OR52A5 | c.427T>C p.L143= | Silent (SNP) | VAF 113/411 reads (27%) | catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- OR5T1 | c.429G>C p.L143= | Silent (SNP) | VAF 90/634 reads (14%) | catalogued as COSV57305243; called by muse, mutect2, varscan2
- OR5T3 | c.477T>C p.A159= | Silent (SNP) | VAF 233/602 reads (39%) | catalogued as COSV57380100; called by muse, mutect2, varscan2
- PARP12 | c.1848G>A p.T616= | Silent (SNP) | VAF 137/437 reads (31%) | catalogued as rs375746909; called by muse, mutect2, varscan2
- PDE11A | c.2679G>A p.P893= | Silent (SNP) | VAF 88/274 reads (32%) | catalogued as rs79512110; called by muse, mutect2, varscan2
- PKHD1 | c.7284C>T p.D2428= | Silent (SNP) | VAF 192/347 reads (55%) | catalogued as rs200807210, COSV61883250; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PLPP4 | c.714C>T p.Y238= | Silent (SNP) | VAF 145/439 reads (33%) | catalogued as rs754115427; called by muse, mutect2, varscan2
- PNMA5 | c.810G>A p.L270= | Silent (SNP) | VAF 80/377 reads (21%) | catalogued as COSV100721603; called by muse, mutect2, varscan2
- PRICKLE2 | c.2427G>A p.S809= (on ENST00000295902; = p.S753= on NM_198859.4) | Silent (SNP) | VAF 163/314 reads (52%) | catalogued as rs769036804; called by muse, mutect2, varscan2
- QKI | c.840A>G p.E280= | Silent (SNP) | VAF 118/587 reads (20%) | called by muse, mutect2, varscan2
- REV3L | c.7449T>C p.N2483= | Silent (SNP) | VAF 13/351 reads (4%) | catalogued as rs1562154032; called by muse, mutect2
- RHBDF2 | c.1344C>T p.S448= | Silent (SNP) | VAF 319/409 reads (78%) | catalogued as rs760283274, COSV51686357; called by muse, mutect2, varscan2
- RPGRIP1 | c.1944C>A p.T648= | Silent (SNP) | VAF 72/952 reads (8%) | called by muse, mutect2
- S1PR5 | c.666C>T p.N222= | Silent (SNP) | VAF 236/724 reads (33%) | catalogued as rs1187276179, COSV100330667, COSV61014366; called by muse, mutect2, varscan2
- SELP | c.2400A>G p.R800= | Silent (SNP) | VAF 13/337 reads (4%) | called by muse, mutect2
- STAC | c.75G>A p.P25= | Silent (SNP) | VAF 149/319 reads (47%) | catalogued as rs771765564, COSV56211616; called by muse, mutect2, varscan2
- STAG3 | c.3114C>T p.V1038= | Silent (SNP) | VAF 70/414 reads (17%) | called by muse, mutect2, varscan2
- TENM1 | c.4359G>A p.Q1453= | Silent (SNP) | VAF 142/315 reads (45%) | catalogued as rs1483884869, COSV100950022, COSV64441908; called by muse, mutect2, varscan2
- TLR4 | c.583T>C p.L195= (on ENST00000355622 / NM_138554.5; = p.L155= on NM_003266.4) | Silent (SNP) | VAF 114/476 reads (24%) | catalogued as COSV100790653, COSV100790676, COSV62922341; called by muse, varscan2
- TSKS | c.480C>T p.H160= | Silent (SNP) | VAF 88/300 reads (29%) | catalogued as rs769543058, COSV55874546; called by muse, varscan2
- TSPOAP1 | c.4137G>A p.Q1379= | Silent (SNP) | VAF 185/806 reads (23%) | called by muse, mutect2, varscan2
- TTC6 | c.774C>T p.D258= | Silent (SNP) | VAF 117/1392 reads (8%) | catalogued as rs1348860946; called by muse, mutect2
- TTLL5 | c.3693C>T p.P1231= | Silent (SNP) | VAF 112/666 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.12426T>C p.I4142= (on ENST00000591111; = p.I4096= on NM_003319.4) | Silent (SNP) | VAF 38/301 reads (13%) | called by muse, mutect2, varscan2
- UBE3A | c.415T>C p.L139= | Silent (SNP) | VAF 68/224 reads (30%) | catalogued as rs1566962877; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF555 | c.1395T>A p.A465= | Silent (SNP) | VAF 138/471 reads (29%) | called by muse, mutect2, varscan2
- ZNF853 | c.1788C>T p.P596= | Silent (SNP) | VAF 101/1259 reads (8%) | called by muse, mutect2
- AC002519.1 | chr16:31793395 C>A | 3'Flank (SNP) | VAF 83/302 reads (27%) | called by muse, mutect2, varscan2
- CORIN | c.2068+132G>A | Intron (SNP) | VAF 85/529 reads (16%) | called by muse, mutect2, varscan2
- KCTD7 | c.453+89A>T | Intron (SNP) | VAF 22/590 reads (4%) | called by muse, mutect2
- LINC00261 | n.164C>T | RNA (SNP) | VAF 193/740 reads (26%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31294A>G | Intron (SNP) | VAF 146/307 reads (48%) | catalogued as COSV99829872; called by muse, mutect2, varscan2
- POU2F2 | c.*91G>T | 3'UTR (SNP) | VAF 112/702 reads (16%) | catalogued as rs1218034291; called by muse, mutect2, varscan2
- SMIM23 | c.434+12C>T | Intron (SNP) | VAF 188/295 reads (64%) | catalogued as rs1352242778; called by muse, mutect2, varscan2
